Somatic mutation profile of tumor specimen MP2PRT-PANYYY-TMP1-A (aliquot MP2PRT-PANYYY-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANYYY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,472 days).
Specimen MP2PRT-PANYYY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0542c023-0171-442a-bb55-c7eac52a66c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANYYY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANYYY-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aa32656-9cc8-4d09-a302-3386b38cd278

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Frame Shift Ins 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIFM3 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 145/394 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59000580; called by muse, mutect2, varscan2
- GRID1 | c.2917G>A p.G973R | Missense Mutation (SNP) | VAF 184/538 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs771866539, COSV60042590, COSV60045727, COSV60050725; called by muse, varscan2
- NEDD4L | c.1535G>A p.R512Q (on ENST00000400345 / NM_001144967.3; = p.R492Q on NM_015277.6) | Missense Mutation (SNP) | VAF 136/329 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1365042367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B1 | c.3181A>T p.I1061F | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ATR | c.3228T>A p.H1076Q | Missense Mutation (SNP) | VAF 160/416 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- BTG1 | c.308_309insTC p.L104Hfs*41 | Frame Shift Ins (INS) | VAF 130/381 reads (34%) | called by mutect2, varscan2
- BTG1 | c.307delinsCCT p.T103Pfs*42 | Frame Shift Ins (INS) | VAF 158/446 reads (35%) | called by mutect2*, pindel, varscan2*
- IGHV5-51 | chr14:106578742 TGTCTC>GGTTTCAGA | Missense Mutation (INS) | VAF 67/117 reads (57%) | called by muse*, pindel
- PDZD4 | c.1123C>T p.L375F | Missense Mutation (SNP) | VAF 213/285 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSG3 | c.770T>A p.V257D | Missense Mutation (SNP) | VAF 132/453 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- GOLGA8M | c.1116C>T p.S372= | Silent (SNP) | VAF 123/410 reads (30%) | called by muse, mutect2, varscan2
- NRXN3 | c.378G>A p.L126= (on ENST00000557594 / NM_001272020.2; = p.L758= on NM_004796.6) | Silent (SNP) | VAF 134/335 reads (40%) | called by muse, mutect2, varscan2
